Somatic mutation profile of tumor specimen HCM-CSHL-0617-C22-01B (aliquot HCM-CSHL-0617-C22-01B-11D-A85K-36) from HCMI case HCM-CSHL-0617-C22, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 86.3 years (31,521 days).
Specimen HCM-CSHL-0617-C22-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ccc800c0-68d3-4bed-9797-33301df043a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0617-C22-11A (Solid Tissue Normal), aliquot HCM-CSHL-0617-C22-11A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c56e7b27-7050-4ff9-a5f1-d996bf9e16da

The open-access MAF lists 64 somatic variants for this specimen: 47 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 15, Nonsense Mutation 3, Intron 2, Frame Shift Del 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS8 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 135/248 reads (54%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.86); catalogued as rs775371580; called by muse, mutect2, varscan2
- ARSB | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 150/378 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.035); catalogued as rs1353600307; called by muse, varscan2
- ASXL3 | c.3032C>T p.P1011L | Missense Mutation (SNP) | VAF 80/133 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1461875148; called by muse, mutect2, varscan2
- CNTNAP5 | c.412G>A p.V138M | Missense Mutation (SNP) | VAF 114/294 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs765263584; called by muse, mutect2, varscan2
- DCC | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 104/212 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs749558240, COSV59091020, COSV59105732; called by muse, mutect2, varscan2
- DIP2C | c.4586C>T p.S1529F | Missense Mutation (SNP) | VAF 120/343 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV55177133; called by muse, mutect2, varscan2
- DNAH9 | c.6704T>C p.I2235T | Missense Mutation (SNP) | VAF 61/142 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764641243; called by muse, varscan2
- EPHA2 | c.2114G>T p.R705L | Missense Mutation (SNP) | VAF 111/199 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV100626236, COSV100626377; called by muse, mutect2, varscan2
- H1-2 | c.76A>G p.K26E | Missense Mutation (SNP) | VAF 82/248 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as rs747091108, COSV59192210; called by muse, varscan2
- KEL | c.868G>T p.E290* | Nonsense Mutation (SNP) | VAF 163/474 reads (34%) | catalogued as COSV62333479; called by muse, mutect2, varscan2
- RP1 | c.512T>G p.L171R | Missense Mutation (SNP) | VAF 103/457 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs1333968200, COSV99606069, COSV99609091; called by muse, mutect2, varscan2
- SCAF4 | c.136A>G p.I46V | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as COSV54590453; called by muse, varscan2
- STK32C | c.1126C>A p.R376S | Missense Mutation (SNP) | VAF 82/229 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV53838935; called by muse, mutect2, varscan2
- VPS13B | c.7339G>T p.G2447C | Missense Mutation (SNP) | VAF 153/288 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100663906; called by muse, mutect2, varscan2
- ANKRD31 | c.2944A>G p.I982V | Missense Mutation (SNP) | VAF 65/238 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATG16L1 | c.1643A>C p.Y548S (on ENST00000392017 / NM_030803.7; = p.Y529S on NM_017974.4) | Missense Mutation (SNP) | VAF 83/247 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- BCL11B | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 125/218 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- CACNA2D3 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 100/246 reads (41%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CCDC110 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 58/174 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.167); called by muse, varscan2
- CDH8 | c.965C>A p.A322E | Missense Mutation (SNP) | VAF 100/264 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CFAP221 | c.1757G>T p.R586I | Missense Mutation (SNP) | VAF 75/262 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- CFAP47 | c.9445C>A p.H3149N | Missense Mutation (SNP) | VAF 100/140 reads (71%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DLG4 | c.1846G>A p.V616M (on ENST00000399506 / NM_001321075.3; = p.V659M on NM_001365.4) | Missense Mutation (SNP) | VAF 87/257 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DSP | c.2500A>T p.K834* | Nonsense Mutation (SNP) | VAF 97/384 reads (25%) | called by muse, mutect2, varscan2
- EPS8 | c.1239G>C p.W413C | Missense Mutation (SNP) | VAF 75/212 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FREM1 | c.703G>T p.V235L | Missense Mutation (SNP) | VAF 114/316 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.071); called by muse, varscan2
- HFM1 | c.932T>C p.V311A | Missense Mutation (SNP) | VAF 83/134 reads (62%) | SIFT tolerated (0.14); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- KCNMB3 | c.460T>G p.C154G | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCTD6 | c.200_201del p.Y67Cfs*17 | Frame Shift Del (DEL) | VAF 72/278 reads (26%) | called by pindel, varscan2
- LEPROTL1 | c.376_378del p.F126del | In Frame Del (DEL) | VAF 31/70 reads (44%) | called by mutect2, pindel, varscan2
- MDGA1 | c.1312G>A p.V438M | Missense Mutation (SNP) | VAF 66/208 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- MICB | c.1138A>G p.T380A | Missense Mutation (SNP) | VAF 23/300 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.295); called by muse, mutect2
- MKRN3 | c.1355G>C p.G452A | Missense Mutation (SNP) | VAF 103/318 reads (32%) | SIFT tolerated (0.87); PolyPhen benign (0.054); called by muse, varscan2
- MYH2 | c.2920A>T p.K974* | Nonsense Mutation (SNP) | VAF 54/237 reads (23%) | called by muse, mutect2, varscan2
- NCKAP5 | c.3878G>T p.G1293V | Missense Mutation (SNP) | VAF 113/363 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR52E1 | c.54_55insT p.L19Sfs*33 | Frame Shift Ins (INS) | VAF 92/310 reads (30%) | called by mutect2, pindel, varscan2
- PLIN4 | c.122C>T p.A41V (on ENST00000301286; = p.A56V on NM_001367868.2) | Missense Mutation (SNP) | VAF 89/286 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PPP4R2 | c.368G>T p.R123I | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- PRRT1 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 160/427 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- RCN3 | c.481T>C p.Y161H | Missense Mutation (SNP) | VAF 95/246 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- SH2D4A | c.1352A>C p.E451A | Missense Mutation (SNP) | VAF 74/129 reads (57%) | SIFT tolerated (0.4); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- STAT5B | c.39A>C p.E13D | Missense Mutation (SNP) | VAF 95/224 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TF | c.269A>G p.Y90C | Missense Mutation (SNP) | VAF 114/319 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, varscan2
- ZFY | c.925T>G p.L309V | Missense Mutation (SNP) | VAF 66/101 reads (65%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- ZNF169 | c.1081C>G p.L361V | Missense Mutation (SNP) | VAF 100/280 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, varscan2
- ZNF512B | c.2089A>G p.I697V | Missense Mutation (SNP) | VAF 166/461 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ZNF623 | c.556A>G p.K186E | Missense Mutation (SNP) | VAF 124/236 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, varscan2
- ACSM2A | c.1479G>C p.V493= (on ENST00000219054; = p.V414= on NM_001308169.2) | Silent (SNP) | VAF 84/319 reads (26%) | called by muse, mutect2, varscan2
- CPZ | c.1323G>T p.G441= (on ENST00000360986 / NM_001014447.3; = p.G430= on NM_003652.3) | Silent (SNP) | VAF 88/224 reads (39%) | called by muse, mutect2, varscan2
- CYP21A2 | c.471C>T p.T157= | Silent (SNP) | VAF 119/594 reads (20%) | catalogued as rs1418676297; called by muse, varscan2
- DDX60 | c.4332T>C p.Y1444= | Silent (SNP) | VAF 77/228 reads (34%) | called by muse, mutect2, varscan2
- HIC2 | c.1509G>A p.R503= | Silent (SNP) | VAF 122/312 reads (39%) | catalogued as rs150684918; called by muse, varscan2
- MYO15B | c.5154C>T p.A1718= | Silent (SNP) | VAF 21/724 reads (3%) | called by muse, mutect2
- NISCH | c.1242G>A p.L414= | Silent (SNP) | VAF 101/256 reads (39%) | called by muse, mutect2, varscan2
- PRAMEF18 | c.828G>A p.R276= | Silent (SNP) | VAF 78/380 reads (21%) | called by muse, varscan2
- SOS1 | c.3057A>G p.R1019= | Silent (SNP) | VAF 55/202 reads (27%) | called by muse, mutect2, varscan2
- UBAP2 | c.1704G>C p.S568= | Silent (SNP) | VAF 66/162 reads (41%) | catalogued as COSV62545015; called by muse, mutect2, varscan2
- VIPR1 | c.351G>A p.P117= | Silent (SNP) | VAF 75/242 reads (31%) | catalogued as rs757213503, COSV57296594; called by muse, varscan2
- WDR72 | c.3261A>T p.P1087= | Silent (SNP) | VAF 63/212 reads (30%) | called by muse, mutect2, varscan2
- ZBTB4 | c.180C>T p.L60= | Silent (SNP) | VAF 198/455 reads (44%) | catalogued as rs763090993; called by muse, mutect2, varscan2
- ZMYM2 | c.4005A>T p.T1335= | Silent (SNP) | VAF 94/173 reads (54%) | called by muse, varscan2
- ZNF729 | c.2832T>C p.A944= | Silent (SNP) | VAF 94/271 reads (35%) | called by muse, mutect2, varscan2
- NAV3 | c.2024-12928C>A | Intron (SNP) | VAF 76/210 reads (36%) | called by mutect2, varscan2
- PDE4DIP | c.441+1771T>C | Intron (SNP) | VAF 224/362 reads (62%) | called by muse, mutect2, varscan2
